Surgical pathology report (de-identified scan), TCGA case TCGA-A2-A1G0, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Walter Reed, specimen TCGA-A2-A1G0-01A (Primary Tumor).

[page 1 of 5]
ICD-0-3

Path: Carcinoma, infiltrating lobular, NOS 8520/3
CQCF: Carcinoma, infiltrating duct 8500/3
Path: Site: breast - upper inner quadrant C50.2
CQCF Site: breast, NOS C50.9
1/25/11 hr

Phone
Fax

Name: [REDACTED]
Acct#: [REDACTED]
Reg: [REDACTED]
Unit#: [REDACTED]
Disch: [REDACTED]
Age/Sex: [REDACTED]
Status: [REDACTED]
Att Dr: [REDACTED]
Location: [REDACTED]
Room/Bed: [REDACTED]

Specimen: [REDACTED]
Received: [REDACTED]
Spec Type: SURGICAL P
Status: [REDACTED]
Subs Dr: [REDACTED]

LEFT BREAST CANCER INVASIVE/RIGHT MAMMOGRAPHIC ABNORMALITY

DATE:

DOCTOR(S):

PROCEDURE: MASTECTOMY COMPLETE SIMPLE WITH SENTINEL NODE BX

- A. LT BREAST SENTINEL NODE #1 - FS
- B. LT BREAST MASTECTOMY
- C. RT BREAST MASTECTOMY
- D. LT AXILLARY NODE DISSECTION
- E. LT BREAST INFERIOR LATERAL SUPERFICIAL MARGIN
- F. RT AXILLARY SKIN

A. METASTATIC CARCINOMA

PART A RECEIVED FRESH LABELED [REDACTED] LEFT MASTECTOMY FIRST SENTINEL NODE, IS AN OVOID PORTION OF RED-TAN TISSUE MEASURING 1.7 X 1.1 X 1.0 CM. SECTIONING REVEALS A PINK-TAN TO GRAY-WHITE CUT SURFACE. A REPRESENTATIVE SECTION IS SUBMITTED AS FSA (MIRROR IMAGE TO PROTOCOL). THE REMAINDER OF THE NODE IS SUBMITTED LABELED A. (L)

PART B RECEIVED LABELED [REDACTED] LEFT MASTECTOMY STITCH AT 12 O'CLOCK, IS A SIMPLE MASTECTOMY MEASURING 25 X 20 X 4.5 CM. THE NIPPLE IS UNREMARKABLE AND SITS WITHIN A 10 X 4.5-CM SKIN ELLIPSE. A SUTURE DENOTES 12 O'CLOCK. THE SUPERFICIAL ASPECT IS MARKED WITH BLUE INK. THE DEEP WITH black. SECTIONING REVEALS THE CENTRAL ASPECT OF THE SPECIMEN TO CONSIST OF DENSE TAN FIBROUS TISSUE WITH AN OVOID TAN FIRM AREA IN THE 11 O'CLOCK AREA, WHICH MEASURES 4.5 CM FROM MEDIAL TO LATERAL, 2.5 CM FROM SUPERIOR TO INFERIOR, AND 2.0 CM FROM SUPERFICIAL TO DEEP. THIS IS 1.3 CM FROM THE DEEP MARGIN. ADDITIONAL FIRM AREAS ARE NOTED. ONE IS AT 12 O'CLOCK SLIGHTLY INFERIOR TO THE PREVIOUSLY DESCRIBED LESION MEASURING 1.1 CM IN DIAMETER. GROSSLY THIS IS 1 CM FROM THE 11 O'CLOCK LESION. A COIL CLIP IS IDENTIFIED IN THE 11 O'CLOCK LESION. IN THE 9 O'CLOCK AREA, THERE IS A 0.7 CM IN DIAMETER LESION, WHICH IS 0.8 CM FROM THE DEEP (L)

[page 2 of 5]
Chief of Pathology

Phone
Fax

Patient: [REDACTED]

(Continued)

Specimen:

Received:

Status: [REDACTED]

Spec Type: SURGICAL P

Subm Dr: [REDACTED]

[REDACTED] (Continued)

MARGIN AND 1.5 CM FROM THE 11 O'CLOCK LESION. B1--NIPPLE, B2--11 O'CLOCK LESION (MIRROR IMAGE TO PROTOCOL IN AREA OF CLIP, B3--11 O'CLOCK LESION WITH DEEP MARGIN, B4--12 O'CLOCK AREA INFERIOR TO THE 11 O'CLOCK LESION, B5--9 O'CLOCK NODULE, B6--9 O'CLOCK AREA SUPERFICIAL TO B5, B7--THE MOST MEDIAL ASPECT OF THE 11 O'CLOCK LESION, B8--THE MOST LATERAL ASPECT OF THE 11 O'CLOCK LESION (4.5 CM FROM B7), B9 AND 10--FULL CROSS SECTION OF 11 O'CLOCK LESION, B11--SECTION OF UPPER INNER QUADRANT SUPERFICIAL TO THE 9 O'CLOCK LESION WITH QUESTIONABLE LESIONAL TISSUE, B12--UPPER INNER QUADRANT NODULARITY SUPERFICIAL TO THE PREVIOUSLY DESCRIBED 9 O'CLOCK LESION AND SUPERIOR TO B11, B13--LOWER INNER QUADRANT, B14--LOWER OUTER QUADRANT, B15--UPPER OUTER QUADRANT.

PART C RECEIVED LABELED [REDACTED] RIGHT MASTECTOMY STITCH AT 12 O'CLOCK, IS A SIMPLE MASTECTOMY SPECIMEN MEASURING 28.5 X 23 X 3.5 CM. THE NIPPLE IS UNREMARKABLE WITHIN A 9 X 4.2-CM SKIN ELLIPSE. THE SUPERFICIAL ASPECT IS MARKED WITH BLUE INK. THE DEEP MARGIN WITH BLACK INK. A SUTURE DENOTES 12 O'CLOCK. SECTIONING REVEALS THE CENTRAL ASPECT OF THE BREAST TO CONSIST OF PALE YELLOW-TAN FIBROUS TISSUE WITH A PERIMETER OF YELLOW FATTY TISSUE, WHICH IS PREDOMINANTLY ON THE LATERAL ASPECT. NO DISTINCT LESIONS ARE PALPATED WITHIN THE SPECIMEN. THERE IS AN AREA WITH RED DISCOLORATION SUGGESTIVE OF A BIOPSY AREA IN THE UPPER OUTER QUADRANT AND A COIL CLIP IS IDENTIFIED. NO ADDITIONAL NODULES ARE IDENTIFIED. SECTIONS ARE SUBMITTED AS FOLLOWS: C1--NIPPLE, C2--CENTRAL DEEP MARGIN, C3 AND 4--UPPER INNER QUADRANT, C5 AND 6--UPPER OUTER QUADRANT, C7 AND 8--LOWER OUTER QUADRANT, C9 AND 10--LOWER INNER QUADRANT, C11 THROUGH 13--ADDITIONAL SECTIONS FROM 9 O'CLOCK AREA. NOTE THAT C1, C3, C5, C7, AND C9 ARE MIRROR IMAGE TO SECTIONS TAKEN PER PROTOCOL. NOTE THAT C5 IN AREA OF COIL CLIP.

PART D RECEIVED LABELED [REDACTED] LEFT AXILLARY NODE DISSECTION, IS YELLOW-RED FATTY TISSUE MEASURING 9.5 X 7.5 X 2.0 CM. THIS IS EXAMINED FOR LYMPH NODES. THE LARGEST NODE MEASURES 4.0 CM IN GREATEST DIMENSIONS AND DEMONSTRATES CENTRAL FAT REPLACEMENT. SECTIONS ARE SUBMITTED AS FOLLOWS: D1--THREE NODES EACH BISECTED, D2--TWO NODES EACH BISECTED, D3--ONE NODE BISECTED, D4--ONE NODE BISECTED, D5--ONE NODE BISECTED, D6--ONE NODE BISECTED, D7--ONE NODE, D8--ONE NODE, D9 THROUGH D12--ONE NODE TOTAL, D13--FOUR NODES, D14--ONE NODE BISECTED, D15--ONE NODE BISECTED, D16--ONE NODE BISECTED, D17--ONE NODE BISECTED.

PART E RECEIVED LABELED [REDACTED] LEFT INFERIOR AND LATERAL SUPERFICIAL MARGIN REEXCISION STITCH AT NEW MARGIN, IS AN IRREGULAR FLAT PORTION OF YELLOW-PINK FATTY TISSUE MEASURING 15.5 X 10.5 X 1.4 CM IN GREATEST DIMENSIONS. A SUTURE DENOTES THE NEW MARGIN AND THIS SIDE IS MARKED WITH BLUE INK. REPRESENTATIVE SECTIONS ARE SUBMITTED LABELED E1 THROUGH 10. APPROXIMATELY 25% OF THE SPECIMEN IS SUBMITTED.

[page 3 of 5]
Chief of Pathology

Phone

Fax (

Patient: [REDACTED]

(Continued)

Specimen:

Received:

Spec Type: SURGICAL P

Status:

Subm Dr: [REDACTED]

(Continued)

PART F RECEIVED LABELED [REDACTED], RIGHT AXILLARY SKIN TISSUE, IS AN ELLIPTICAL PORTION OF TAN SKIN MEASURING 3.3 X 1.5 X 0.7 CM. THIS IS NOT OTHERWISE ORIENTED. THERE IS A FULL-THICKNESS SLIT-LIKE DEFECT ON THE SURFACE MEASURING 0.7 CM IN LENGTH. THE MARGIN IS MARKED WITH BLACK INK WITH THE SLIT-LIKE DEFECT MARKED BLUE. THIS IS SECTIONED ACROSS THE NARROW MARGIN AND SUBMITTED SEQUENTIALLY LABELED F1 AND 2.

PROCEDURES:

88307/3, 88309, PATH FS , A BLK, B BLK/15, C BLK/13, D BLK/17, E BLK/10, F BLK/2, FS-A

PART A LEFT AXILLA, SENTINEL LYMPH NODE BIOPSY NUMBER 1: METASTATIC CARCINOMA CONSISTENT WITH BREAST PRIMARY HAVING A MAXIMUM MICROSCOPIC DIMENSION OF 8 MM AND SHOWING EXTRANODAL EXTENSION.

PART B LEFT BREAST, SIMPLE MASTECTOMY:

1. WELL-DIFFERENTIATED INFILTRATING TUBULOLOBULAR CARCINOMA, NUCLEAR GRADE 1, LOW MITOTIC INDEX AND TUBULE FORMATION 2 WITH TOTAL NOTTINGHAM SCORE OF 4.
2. LARGEST GROSS TUMOR INVOLVES THE 11 O'CLOCK AREA MEASURING 4.5 CM IN GREATEST DIMENSION. ADDITIONAL SIMILAR TUMOR NODULES ARE MULTIFOCALLY NOTED WITHIN THE SAME QUADRANT AT THE 12 O'CLOCK, 9 O'CLOCK, SUPERFICIAL UPPER INNER QUADRANT AND SUPERIOR UPPER INNER QUADRANT RANGING FROM 0.5 TO 1 CM IN GREATEST MICROSCOPIC DIMENSION.
3. THE NIPPLE SKIN, RANDOM SECTIONS OF THE REMAINING QUADRANTS AND MARGINS OF EXCISION ARE FREE OF TUMOR.
4. LYMPHOVASCULAR INVASION IS PRESENT.
5. THE BIOPSY SITE IS IDENTIFIED.
6. PROLIFERATIVE FIBROCYSTIC CHANGES ARE SEEN IN RANDOM SECTIONS FROM THE REMAINING QUADRANTS.

PART C RIGHT BREAST, SIMPLE MASTECTOMY: PATCHY AREAS OF PSEUDOANGIOMATOUS HYPERPLASIA AND FIBROCYSTIC CHANGES INCLUDING USUAL DUCTAL HYPERPLASIA, APOCRINE METAPLASIA, MICROCYST FORMATION AND PATCHY DENSE STROMA. BIOPSY SITE IS PRESENT. NEGATIVE FOR

[page 4 of 5]
Chief of Pathology

Phone

Fax

Patient: [REDACTED]

(Continued)

Specimen:

Received:

Status:

Spec Type: SURGICAL P

Subm Dr: [REDACTED]

[REDACTED] (Continued)

EPITHELIAL ATYPIA.

PART D LEFT AXILLA, LYMPH NODE DISSECTION: METASTATIC BREAST CARCINOMA IS IDENTIFIED IN 1 OF 18 LYMPH NODES EXAMINED WHICH HAS FOCAL INVASION INTO THE PERINODAL FAT.

PART E LEFT BREAST, REEXCISION OF LEFT INFERIOR AND LATERAL SUPERFICIAL MARGINS: FATTY BREAST TISSUE WITH NO EVIDENCE OF RESIDUAL TUMOR AND CLEAR MARGIN.

PART F SKIN, RIGHT AXILLA, BIOPSY: FOCAL SUPRABASAL DETACHMENT OF THE EPIDERMIS WITH ASSOCIATED CAUTERY ARTIFACT. NO EVIDENCE OF NEOPLASM OR SIGNIFICANT INFLAMMATION.

Signed _____ (signature on file) _____

Pin TSS, TCGA tumor is infiltrating ductal, not lobular. Path dx discrepancy form will be completed by TSS. 3/10/15

[page 5 of 5]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name) _____ Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Tubulolobular Ca.	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	_____	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	Tubulolobular Ca diagnosed at outside institution. IHC staining done by and read by supports IDC diagnosis.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director	_____	Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file 2ede69ac-3fe9-48ef-8653-b96bd4f28cab (TCGA-A2-A1G0.DA82E751-09C3-466E-A63A-38368D8A2C7C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).